Somatic mutation profile of tumor specimen TCGA-DB-5274-01A (aliquot TCGA-DB-5274-01A-01D-1468-08) from TCGA case TCGA-DB-5274, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.5 years (13,680 days).
Specimen TCGA-DB-5274-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4cfdd5d-f29f-421e-a09d-13f0fbde4375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5274-10A (Blood Derived Normal), aliquot TCGA-DB-5274-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4cc699d-518f-4627-b77b-af465dadc20c

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 19, Silent 12, Frame Shift Del 5, Splice Site 2, In Frame Del 2, Frame Shift Ins 2, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 49/166 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATG2B | c.5577T>C p.H1859= | Splice Region (SNP) | VAF 20/188 reads (11%) | catalogued as rs753551587, COSV55890817; called by muse, varscan2
- BGN | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59037306; called by muse, mutect2, varscan2
- BTBD8 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV61546719; called by muse, mutect2
- C1orf56 | c.1005+3_1005+6del p.X335_splice | Splice Site (DEL) | VAF 38/145 reads (26%) | catalogued as rs1320396834; called by mutect2, pindel, varscan2
- ESR2 | c.1582_1583del p.Q528Vfs*18 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs779856508; called by pindel, varscan2
- FEM1C | c.1734C>G p.I578M | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as COSV57231859; called by muse, mutect2, varscan2
- GRIA3 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 17/376 reads (5%) | catalogued as COSV52066645; called by muse, mutect2
- HLA-DQA2 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV66565769; called by muse, mutect2, varscan2
- LTN1 | c.267del p.M90Cfs*10 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | catalogued as COSV100798111; called by mutect2, pindel, varscan2
- MAST4 | c.2951A>C p.E984A (on ENST00000403625 / NM_001164664.2; = p.E795A on NM_015183.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV55129508; called by muse, mutect2, varscan2
- MRGPRX3 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs184402606; called by muse, mutect2, varscan2
- NLRP13 | c.2148C>G p.N716K | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs144412914, COSV61622401; called by muse, mutect2, varscan2
- OR5L2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV65723523, COSV65724355; called by muse, mutect2, varscan2
- POLR3B | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371453512, COSV99943782; called by muse, mutect2, varscan2
- PREX1 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as COSV64253136; called by muse, mutect2
- SH3GL3 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61058005; called by muse, mutect2, varscan2
- SLC38A6 | c.309A>G p.T103= | Splice Region (SNP) | VAF 15/222 reads (7%) | catalogued as rs1024723234, COSV50783206; called by muse, mutect2
- ST3GAL4 | c.562G>A p.V188I (on ENST00000392669 / NM_001254758.1; = p.V184I on NM_006278.3) | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs1252070575, COSV57108048; called by muse, mutect2, varscan2
- STAG1 | c.2267C>G p.S756C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs371711194, COSV99365266; called by muse, mutect2, varscan2
- STON2 | c.1578A>C p.K526N (on ENST00000649389 / NM_001366849.2; = p.K469N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50846486; called by muse, mutect2
- TMEM132B | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54757041; called by muse, mutect2
- TMEM245 | c.1031C>G p.T344R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV65823253, COSV65824651; called by muse, mutect2, varscan2
- TPR | c.3021G>C p.K1007N | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV66601817, COSV66602173; called by muse, mutect2
- ZNF334 | c.1242_1244del p.F415del | In Frame Del (DEL) | VAF 40/182 reads (22%) | catalogued as rs769847405; called by pindel, varscan2
- ZNF41 | c.1563A>C p.K521N | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57441330; called by muse, mutect2, varscan2
- ABCA8 | c.3009dup p.I1004Hfs*3 | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- EPC2 | c.648_649del p.K217Nfs*8 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- FUBP1 | c.446_449del p.M149Kfs*42 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- FUBP1 | c.248_250+1del p.X83_splice | Splice Site (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- MYH15 | c.5613_5615del p.K1871del | In Frame Del (DEL) | VAF 48/162 reads (30%) | called by pindel, varscan2
- OGT | c.61_64del p.F21Kfs*3 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by pindel, varscan2
- PABPC1 | c.28dup p.M10Nfs*66 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- C6 | c.2619T>C p.C873= | Silent (SNP) | VAF 213/493 reads (43%) | catalogued as COSV54711980; called by muse, mutect2, varscan2
- CD82 | c.117C>T p.S39= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as COSV57035548; called by muse, mutect2, varscan2
- GLUD2 | c.228C>T p.R76= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as COSV60152016; called by muse, mutect2
- HHAT | c.1140C>T p.G380= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs139136517; called by muse, mutect2
- HOXA4 | c.718C>T p.L240= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV57827160; called by muse, mutect2, varscan2
- HSPG2 | c.1449C>T p.N483= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs529678982, COSV65930428; called by muse, mutect2, varscan2
- PTCHD1 | c.210T>G p.V70= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV65061241; called by muse, mutect2
- RBP1 | c.309G>A p.E103= (on ENST00000619087 / NM_001365940.2; = p.E165= on NM_002899.5) | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV51677265; called by muse, mutect2
- RFX6 | c.63C>T p.S21= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs766273907, COSV60586198; called by muse, mutect2, varscan2
- SLITRK4 | c.1650C>T p.S550= | Silent (SNP) | VAF 88/252 reads (35%) | catalogued as rs1163109428, COSV62024193, COSV62024335; called by muse, mutect2, varscan2
- TLR7 | c.3093C>T p.N1031= | Silent (SNP) | VAF 89/295 reads (30%) | catalogued as rs201628325, COSV66124582; called by muse, mutect2, varscan2
- TTN | c.3390G>A p.V1130= (on ENST00000591111; = p.V1084= on NM_003319.4) | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV59965071; called by muse, mutect2, varscan2
